Surgical pathology report (de-identified scan), TCGA case TCGA-4T-AA8H, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Duke University, specimen TCGA-4T-AA8H-01A (Primary Tumor).

[page 1 of 4]
Results

Surgical Pathology

Result Data

ACCESSION

Entry Date

Component Results

Component

Lab

Clinical History

Malignant neoplasm of sigmoid colon.

Gross Examination

A. "Left paratubal cyst with left tubal fimbria". Received fresh and placed in formalin at [REDACTED] is a 1.5 x 1.5 x 1.0 cm fragment of fimbria with attached 3.5 x 3.0 x 3.0 cm paratubal cyst. The cyst is unilocular and filled with clear serous fluid. The cyst wall is less than 0.1 cm thick and has a smooth internal lining. Representative sections are submitted as follows:

BLOCK SUMMARY:

- A1- fimbriated end, bisected
- A2- representative sections of cyst wall
- A3-9- remainder of specimen

B. "Descending and sigmoid colon, stitch marks distal". received and placed in formalin on [REDACTED]

Specimen received: Descending colon and sigmoid colon.
Colon length: 21.5 cm.

Tumor location: Descending colon.
Tumor dimensions: 5.2 x 4.7 x 1.2 cm
Tumor appearance: Exophytic, lobulated, and focally friable. On cut surface, the mass displays elongated cystic spaces within the bowel wall which are filled with friable tumor material.

Distance from margins:

Proximal: 2.8 cm.
Distal: 13.5 cm.
Mesenteric: 2.0 cm.

Bowel circumference at tumor site: 7.2 cm.

Circumferential growth: 75%.

Depth of invasion: 2.2 cm.

Deepest invasion: The mass invades through the bowel wall, into the fat and puckers the underlying serosa (inked blue).

Tumor perforation: No.

Involvement of adjacent structures: No.

Mesentery dimensions: 20.0 x 7.0 x 2.0 cm

Serosa: The serosa is focally puckered underlying the mass (blue ink). The puckering comes within 3.5 cm of the proximal margin.

Lymph nodes: Multiple lymph nodes are identified, up to 1.0 cm in greatest dimension.

ICD O3
Adenocarcinoma, mucinous NOS 8480/3
Site: Ascending colon C18.6
J 6/13/14

[page 2 of 4]
[REDACTED]

Secondary findings: The remainder of the bowel mucosa is tan, velvety, with normal folding pattern. There is focal submucosal tattooing, 2.5 cm proximal to the mass.

Special studies

prospectively ordered: No
Photograph: Yes.
Block diagram: No.
Tissue submitted for research: Yes, tumor and normal.

BLOCK SUMMARY:

B1-B2- proximal margin
B3-B4- distal margin
B5- mass, deepest invasion with serosal puckering
B6-B10- additional sections of mass
B11- mass to closest mesenteric margin
B12- representative normal colon with tattoo
B13- six lymph nodes
B14- six lymph nodes
B15- four lymph nodes
B16- four lymph nodes
B17- four lymph nodes
B18- four lymph nodes
B19- one lymph node, bisected
B20- one lymph node bisected

[REDACTED]

Microscopic Examination

Microscopic examination is performed. Within part A, the fallopian tube fimbria demonstrates a focal area of mild cytologic atypia. Immunohistochemistry of this area (block A1) reveals weak/low cytokeratin 7, p53 and Ki67 expression. Cytokeratin 20, Pax8 and CDX2 are negative. In comparison, the tumor present in the colon demonstrates strong cytokeratin 20 and CDX2 expression and is negative for Pax8, p53, and cytokeratin 7. Ki67 is moderately elevated. Overall, the findings in the fallopian tube are felt to be secondary to cautery artifact. Dr. [REDACTED] has reviewed parts of this case and concurs with the interpretation.

Immunohistochemical Findings

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the [REDACTED]. Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

Pathologic Stage

PATHOLOGIC STAGE (AJCC 7th Edition): pT3 pN0 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it.

[page 3 of 4]
[REDACTED]

The exact operative procedure is available in the surgeon's operative report.
Diagnosis

A. LEFT FALLOPIAN TUBE FIMBRIA AND PARATUBAL CYST, EXCISION:
BENIGN PARATUBAL CYST.

B. DESCENDING AND SIGMOID COLON, RESECTION:
INVASIVE ADENOCARCINOMA OF THE LEFT COLON.

Histologic type:	MUCINOUS ADENOCARCINOMA.
Histologic Grade:	LOW GRADE.
Tumor size:	5.2 x 4.7 x 1.2 CM.
Extent of invasion:	TUMOR INVADES THROUGH THE MUSCULARIS PROPRIA INTO THE PERICOLONIC ADIPOSE TISSUE.
Macroscopic Tumor	
Perforation:	NOT IDENTIFIED.
Margins:	NEGATIVE.
- Closest Margin:	MESENTERIC, 2.0 CM..
Lymphovascular Invasion:	NOT IDENTIFIED.
Perineural Invasion:	NOT IDENTIFIED.
Tumor Deposits:	NOT IDENTIFIED.
Tumor Infiltrating	
Lymphocytes:	ABSENT.
Marked Crohn's-like	
Lymphocytic Response:	PRESENT.
Regional Lymph Nodes:	TWENTY-FOUR LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/24).
Additional Findings	TATTOO INK IS PRESENT.

NOTE: MSI and/or mismatch repair protein IHC testing will be reported separately (paraffin block B6).

Comment:

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] M.D.
Electronically signed: [REDACTED]

Testing Performed By

Lab - Abbreviation	Name	Director	Address	Valid Date Range
		[REDACTED]		

Lab and Collection

Surgical Pathology on [REDACTED]

Result Information

Abnormality	Status	Priority	Source
	Final result [REDACTED]	Routine	

Authorizing Provider Information

Name: [REDACTED] MD Fax: [REDACTED]
Phone: [REDACTED] Pager: [REDACTED]

Surgical Pathology (Order

[REDACTED]	Authorizing: [REDACTED] MD	Date [REDACTED]
Pathology and Cytology	Department [REDACTED] General	Released By: [REDACTED]
Order: [REDACTED]	Surgery	[REDACTED]

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

[page 4 of 4]
[REDACTED]

[REDACTED] [REDACTED] [REDACTED] [REDACTED]

Order Details

Frequency
Once

Duration
1 occurrence

Priority
Routine

Encounter

[View Encounter](#)

Reprint Requisition

Surgical Pathology (Order # [REDACTED] for [REDACTED])

Original Order

Ordered On

Ordered By

Collection Information

Collection Date

Resulting Agency

Order Provider Info

Ordering User

Authorizing Provider

MD

Office
phone

Pager/beeper

E-mail

Order-Level Documents:

There are no order-level documents.

No order transmittal information available.

Order may not have completed order transmittal.

[REDACTED]

Source: NCI Genomic Data Commons file 214eb83c-3dc8-414b-9b20-0ee4adf4412b (TCGA-4T-AA8H.FAB79463-7351-4C25-9AEC-7B47486C7F54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).